Somatic mutation profile of tumor specimen ALCH-AEKM-TTP1-A (aliquot ALCH-AEKM-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AEKM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.0 years (21,930 days).
Specimen ALCH-AEKM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95bb6725-d30a-4375-8f2e-d5f75d6eb2c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEKM-NB1-A (Blood Derived Normal), aliquot ALCH-AEKM-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e17d4dc-e010-4c79-ada9-5f61c1cb1c51

The open-access MAF lists 31 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 7, Intron 2, Frame Shift Del 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAZ2B | c.6413C>T p.T2138I | Missense Mutation (SNP) | VAF 89/703 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as rs1056073335; called by muse, mutect2, varscan2
- EIF5A2 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 83/852 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1464170994; called by muse, mutect2
- GJB4 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 27/261 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.576); catalogued as rs1339282234; called by muse, mutect2, varscan2
- LRCH4 | c.1486C>T p.R496W | Missense Mutation (SNP) | VAF 76/337 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as rs761681238; called by muse, mutect2, varscan2
- ORM2 | c.163T>C p.Y55H | Missense Mutation (SNP) | VAF 182/1037 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1213738432; called by mutect2, varscan2
- RECQL5 | c.1099G>T p.D367Y | Missense Mutation (SNP) | VAF 33/347 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100512403; called by muse, mutect2
- SLC9A7 | c.2041G>A p.A681T | Missense Mutation (SNP) | VAF 66/615 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs375953952, COSV60378801; called by muse, mutect2, varscan2
- SOX6 | c.2134C>T p.Q712* (on ENST00000528429 / NM_001145819.2; = p.Q685* on NM_017508.3) | Nonsense Mutation (SNP) | VAF 162/1122 reads (14%) | catalogued as COSV57060934; called by muse, mutect2, varscan2
- EFCAB2 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- EHMT1 | c.3508G>A p.E1170K | Missense Mutation (SNP) | VAF 71/630 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- GLI3 | c.3395_3396del p.P1132Rfs*114 | Frame Shift Del (DEL) | VAF 23/102 reads (23%) | called by mutect2, pindel, varscan2
- H2BW2 | c.67C>A p.Q23K | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- HIC1 | c.880T>C p.F294L (on ENST00000322941 / NM_001098202.1; = p.F275L on NM_006497.4) | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- IGHM | c.470C>A p.S157Y | Missense Mutation (SNP) | VAF 103/493 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- IWS1 | c.2420C>T p.A807V | Missense Mutation (SNP) | VAF 28/410 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- KIF1A | c.3959G>A p.S1320N (on ENST00000320389 / NM_001379639.1; = p.S1312N on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/298 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.169); called by muse, mutect2
- MAN2A1 | c.1275T>A p.D425E | Missense Mutation (SNP) | VAF 204/937 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NCAM1 | c.2282G>A p.G761E (on ENST00000316851 / NM_181351.5; = p.G751E on NM_000615.7) | Missense Mutation (SNP) | VAF 44/388 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RAB11FIP3 | c.1170T>G p.F390L | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- THOC5 | c.1901A>G p.D634G | Missense Mutation (SNP) | VAF 37/298 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ZYG11A | c.1948G>T p.A650S | Missense Mutation (SNP) | VAF 42/364 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HECW2 | c.3705C>A p.G1235= | Silent (SNP) | VAF 31/659 reads (5%) | called by muse, mutect2
- KIF1A | c.2946C>T p.A982= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as rs1197824395, COSV100239439; called by muse, varscan2
- PCDHA6 | c.1314C>T p.T438= | Silent (SNP) | VAF 99/569 reads (17%) | catalogued as COSV65342944; called by muse, mutect2, varscan2
- RHCE | c.255G>A p.A85= | Silent (SNP) | VAF 100/736 reads (14%) | catalogued as rs1375801373; called by muse, mutect2, varscan2
- SIPA1L2 | c.3936G>A p.K1312= | Silent (SNP) | VAF 56/301 reads (19%) | catalogued as rs1212300418; called by muse, mutect2, varscan2
- SLC35F1 | c.312C>T p.L104= | Silent (SNP) | VAF 29/246 reads (12%) | catalogued as rs976683206, COSV64501250; called by muse, mutect2, varscan2
- SNX27 | c.1197C>A p.S399= | Silent (SNP) | VAF 72/630 reads (11%) | called by muse, mutect2, varscan2
- AC136759.1 | n.1202C>T | RNA (SNP) | VAF 124/862 reads (14%) | catalogued as rs559542427; called by muse, mutect2, varscan2
- FCRLB | c.574+201C>T | Intron (SNP) | VAF 28/210 reads (13%) | called by muse, mutect2, varscan2
- MAPT | c.1732+2350T>C | Intron (SNP) | VAF 32/149 reads (21%) | called by muse, mutect2, varscan2
